Surgical pathology report (de-identified scan), TCGA case TCGA-DC-4745, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-4745-01A (Primary Tumor).

[page 1 of 4]
* Addendum *

Clinical Diagnosis & History:
Rectosigmoid adenocarcinoma,

Specimens Submitted:

- 1: SP: Sigmoid and upper rectum
- 2: SP: Proximal anastomotic ring
- 3: SP: Distal anastomotic ring

DIAGNOSIS:

- 1) SIGMOID AND UPPER RECTUM; PARTIAL COLECTOMY;
- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: RECTOSIGMOID
- TUMOR SIZE: LENGTH IS 3 CM, WIDTH IS 3 CM AND MAXIMAL THICKNESS IS 0.6 CM.
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): NOT IDENTIFIED.
- TUMOR INVASION: INVASION INTO SUBSEROSEA.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS: FREE OF TUMOR, 3 CM FROM THE DISTAL RESECTION MARGIN; 3 CM BETWEEN DEEPEST TUMOR PORTION AND DEEP (RADIAL, SOFT TISSUE) MARGIN.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS [REDACTED]: pT3
- LYMPH NODES: NUMBER WITH METASTASES (1); NUMBER EXAMINED (22).
- THE PATHOLOGIC STAGE IS [REDACTED]: pN1
- THE RESULTS OF IMMUNOHISTOCHEMICAL STAINS FOR MISMATCH REPAIR PROTEINS WILL BE REPORTED IN AN ADDENDUM.
- 2) COLON, ANASTOMOTIC RING, PROXIMAL; EXCISION;
- SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.
- 3) RECTUM, ANASTOMOTIC RING, DISTAL; EXCISION;
- SEGMENT OF COLON WITH NO PATHOLOGIC DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED

** Continued on next page **

[page 2 of 4]
1). The specimen is received fresh and is labeled "sigmoid and upper rectum, stitch marks proximal". It consists of a rectosigmoid colon that measure 16.0 x 5.0 x 0.6 cm. The serosal surface is tan-pink, smooth and grossly unremarkable. The radial resection margin and serosa are inked black. Specimen is opened to reveal a tumor that is located 10.0 cm from the proximal margin and 3.0cm from the distal margin. The tumor measures 3.0 cm in length and 3.0 cm in width. Serial sectioning reveals tumor is 0.6 cm in depth and is 3.0cm from the closest radial margin. There is no muscular invasion grossly. The remaining mucosa is tan-pink and grossly unremarkable.

Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

RM - radial margin

T - tumor

U - uninvolved mucosa

LN - lymph nodes

2). The specimen is received in formalin, labeled "proximal anastomotic ring" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a 1.5cm long blue plastic piece is noted. A ring of pink tan soft tissue is attached measuring 1.8cm in diameter and 1.2cm in length. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the representative section of soft tissue is submitted.

Summary of sections:

U - undesignated

3). The specimen is received in formalin, labeled "distal anastomotic donut" and consists of a ring of pink tan soft tissue measuring 1.7x1.5x1.0 Cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and representative section of soft tissue is submitted.

Summary of sections:

U - undesignated

** Continued on next page **

[page 3 of 4]
Summary of Sections:

Part 1: SP: Sigmoid and upper rectum

Block	Sect.	Site	PCs
5		{not entered}	
1		DM	1
6		LN	18
1		PM	1

Part 2: SP: Proximal anastomotic ring

Block	Sect.	Site	PCs
1		U	1

Part 3: SP: Distal anastomotic ring

Block	Sect.	Site	PCs
1		U	1

Addendum Diagnosis

Results of immunohistochemical staining for DNA mismatch repair proteins are as follows:

MLH1: (X) Staining present in tumor
() Staining absent in tumor
() Staining inconclusive

MSH2: (X) Staining present in tumor
() Staining absent in tumor
() Staining inconclusive

MSH6: (X) Staining present in tumor
() Staining absent in tumor
() Staining inconclusive

PMS2: (X) Staining present in tumor
() Staining absent in tumor
() Staining inconclusive

** Continued on next page **

[page 4 of 4]
----- Page 4 of 4
Conclusion:

- Immunohistochemical staining for the tested DNA mismatch repair proteins is retained in the tumor.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement [REDACTED] as qualified to perform high complexity clinical laboratory testing.

** End of Report **

Source: NCI Genomic Data Commons file 4f2b5ca8-8e44-4cdb-887c-37689d7edf61 (TCGA-DC-4745.04B9416D-3DE4-48AC-83EB-B18931C3C995.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).